Somatic mutation profile of tumor specimen 0DFYQQ from CCDI case PBBSVE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.7 years (5,738 days).
Specimen 0DFYQQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca1e2480-1c60-4fe0-b74c-c5557e778a56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFYPI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e8266da-b783-4a84-a374-9ac396795134

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, In Frame Del 1, Frame Shift Del 1, Splice Site 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 173/458 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID3A | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 130/248 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773129754; called by muse, mutect2
- BBX | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 152/583 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168225341, COSV57880212, COSV57881518, COSV57884048; called by muse, mutect2, varscan2
- CNDP2 | c.457-2A>G p.X153_splice | Splice Site (SNP) | VAF 93/165 reads (56%) | catalogued as rs1169621623; called by muse, mutect2, varscan2
- GNAS | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 526/542 reads (97%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CM013732; called by muse, mutect2, varscan2
- NUP62CL | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 81/85 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1358527523; called by muse, mutect2, varscan2
- POTEH | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 68/910 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.576); catalogued as rs754486088, COSV100624793, COSV100624911; called by muse, mutect2
- RPAP2 | c.155T>C p.I52T | Missense Mutation (SNP) | VAF 162/336 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs749684168; called by muse, mutect2, varscan2
- ARHGEF35 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 158/498 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCNB3 | c.2401C>A p.L801I | Missense Mutation (SNP) | VAF 146/152 reads (96%) | SIFT tolerated (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CEP290 | c.6763G>A p.G2255S | Missense Mutation (SNP) | VAF 288/595 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DDX3X | c.1604G>A p.G535E (on ENST00000399959; = p.G536E on NM_001356.5) | Missense Mutation (SNP) | VAF 178/208 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNS3 | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR1N2 | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- SRGAP2C | c.44_46del p.A15del | In Frame Del (DEL) | VAF 100/634 reads (16%) | called by mutect2, pindel
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 10/340 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- XPO1 | c.966_967del p.S323Ffs*8 | Frame Shift Del (DEL) | VAF 144/406 reads (35%) | called by mutect2, pindel, varscan2
- ZFR2 | c.975C>T p.A325= | Silent (SNP) | VAF 140/341 reads (41%) | catalogued as rs374439423; called by muse, mutect2, varscan2
- PSMG1 | c.134+67A>G | Intron (SNP) | VAF 36/81 reads (44%) | catalogued as rs892271544; called by muse, varscan2
